Gene-level copy-number profile of tumor specimen TCGA-BT-A2LB-01A from TCGA case TCGA-BT-A2LB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.5 years (26,846 days).
Specimen TCGA-BT-A2LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.50257d82-1d0d-406f-bccf-57793057e37d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A2LB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac6a2e89-be61-480d-ad0d-293553f1bc5e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,462; copy number 2: 18,650; copy number 3: 19,118; copy number 4: 19,666; copy number 5: 459; copy number 6: 98; copy number 7: 31; copy number 9: 78; copy number 13: 126; copy number 14: 119; copy number 19: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A2LB-01A-11D-A18E-01): tumor purity 0.5, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:98,606,833–99,070,792, 8 genes: SEPTIN7P7, ANKS6, AL807776.1, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 358 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:111,979,010–118,810,836, 102 genes, copy number 9–14 (broad region; genes not listed).
- chr3:119,146,151–128,502,970, 225 genes, copy number 13–19 (broad region; genes not listed).
- chr16:20,028,239–21,159,441, 31 genes, copy number 7: GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1, DNAH3, AC008551.1.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
